Somatic mutation profile of tumor specimen TCGA-CN-5355-01A (aliquot TCGA-CN-5355-01A-01D-1434-08) from TCGA case TCGA-CN-5355, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 64.8 years (23,670 days).
Specimen TCGA-CN-5355-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 203b98f7-ee2d-4b54-8267-6c9cf0f89171.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5355-10A (Blood Derived Normal), aliquot TCGA-CN-5355-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcaa835d-1508-4455-8042-b8313ae13556

The open-access MAF lists 112 somatic variants for this specimen: 85 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 24, Frame Shift Ins 4, Nonsense Mutation 4, 3'Flank 2, Splice Site 2, Frame Shift Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993G>A p.Q331= | Splice Region (SNP) | VAF 61/147 reads (41%) | catalogued as rs11575996, CS125161, COSV52681350, COSV52690011, COSV52951377, COSV99391417; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11155T>G p.F3719V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101447157; called by muse, mutect2, varscan2
- ACSM2B | c.1483A>C p.S495R | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100313054; called by muse, mutect2, varscan2
- ADCY8 | c.3359G>A p.R1120Q | Missense Mutation (SNP) | VAF 70/407 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs889544437, COSV53900258; called by muse, mutect2, varscan2
- ADGRL4 | c.1716G>T p.W572C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210828859, COSV100876462; called by muse, mutect2, varscan2
- AHCYL2 | c.1414A>G p.S472G | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773323582, COSV100273682; called by muse, mutect2, varscan2
- ALPK1 | c.3262G>C p.A1088P | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51584665, COSV99455002; called by muse, mutect2, varscan2
- APOBEC3B | c.672C>A p.D224E | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.041); catalogued as COSV100213854; called by muse, mutect2, varscan2
- ARID2 | c.2264C>T p.T755I | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.299); catalogued as COSV100536838; called by muse, mutect2, varscan2
- BCL2L11 | c.461G>T p.R154L (on ENST00000393256 / NM_138621.5; = p.R94L on NM_006538.5) | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100427459; called by muse, mutect2, varscan2
- BCL9L | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV100600148; called by muse, mutect2, varscan2
- BICC1 | c.546+1G>C p.X182_splice | Splice Site (SNP) | VAF 5/85 reads (6%) | catalogued as COSV100874892; called by muse, mutect2
- BTAF1 | c.2515C>A p.Q839K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.09); catalogued as COSV99795710; called by muse, mutect2, varscan2
- BTBD9 | c.1291G>T p.A431S | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100022520; called by muse, mutect2, varscan2
- C22orf31 | c.796T>G p.F266V | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99326499; called by muse, mutect2, varscan2
- C9orf135 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs965232758, COSV65877325; called by muse, mutect2, varscan2
- CAPN15 | c.2699A>T p.H900L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99562736; called by muse, mutect2, varscan2
- CDH9 | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99151328; called by muse, mutect2, varscan2
- CNTLN | c.725A>T p.N242I | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV99265333; called by muse, mutect2, varscan2
- CSMD3 | c.846A>G p.I282M | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV99844654; called by muse, mutect2, varscan2
- CXCL10 | c.157G>C p.A53P | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100134124; called by muse, mutect2, varscan2
- DEPDC7 | c.1502A>T p.H501L (on ENST00000241051 / NM_001077242.2; = p.H492L on NM_139160.2) | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV99572866; called by muse, mutect2, varscan2
- EDC4 | c.628A>T p.N210Y | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV99534569; called by muse, mutect2, varscan2
- EML4 | c.2699C>G p.P900R | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as COSV100581229, COSV59299792; called by muse, mutect2, varscan2
- EPHB4 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776305185, COSV100639623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM135B | c.2083G>T p.V695F | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.116); catalogued as rs374779918, COSV99426694; called by muse, mutect2, varscan2
- FOXP4 | c.1807C>A p.L603I (on ENST00000307972 / NM_001012426.1; = p.L590I on NM_138457.3) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV100332977; called by muse, mutect2
- GRM1 | c.2794C>A p.P932T | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV99268482; called by muse, mutect2, varscan2
- GRM6 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); catalogued as rs150850494; called by muse, mutect2, varscan2
- HECTD4 | c.11072C>T p.A3691V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); catalogued as rs1036172260, COSV101108319; called by muse, mutect2, varscan2
- IGSF9B | c.257A>T p.Y86F | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV100318257; called by muse, mutect2
- IL12A | c.377A>T p.K126M | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99975857; called by muse, mutect2, varscan2
- IMMP2L | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100072708, COSV59246301; called by muse, mutect2, varscan2
- ISL1 | c.905A>T p.D302V | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV100045649; called by muse, mutect2, varscan2
- KDM6A | c.2702G>T p.R901M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100938522, COSV65037143, COSV65039959; called by muse, mutect2, varscan2
- KLHL28 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.142); catalogued as COSV100753253, COSV61888840; called by muse, mutect2, varscan2
- KRTAP13-3 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100481820; called by muse, mutect2, varscan2
- LPCAT2 | c.1061A>G p.K354R | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV100045211; called by muse, mutect2, varscan2
- LRIG3 | c.1533A>G p.I511M | Missense Mutation (SNP) | VAF 73/288 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV100292796; called by muse, mutect2, varscan2
- LRP1B | c.7921A>T p.T2641S | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV101259756; called by muse, mutect2, varscan2
- MAGEL2 | c.2377A>T p.T793S | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.722); catalogued as COSV100046160; called by muse, mutect2, varscan2
- MARCHF7 | c.944A>T p.Y315F | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99374036; called by muse, mutect2, varscan2
- MARK1 | c.1643G>T p.R548L | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV100857491, COSV99081354; called by muse, mutect2, varscan2
- MDC1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.406); catalogued as rs777255794, COSV64526783; called by muse, mutect2, varscan2
- MDGA2 | c.1877T>G p.V626G (on ENST00000399232 / NM_001113498.2; = p.V328G on NM_182830.4) | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100638101, COSV62111572, COSV62112746; called by muse, mutect2, varscan2
- MICAL1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as COSV100668723; called by muse, mutect2, varscan2
- MTNR1B | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs373501373, COSV57066914; called by muse, mutect2, varscan2
- NADSYN1 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100034993; called by muse, mutect2, varscan2
- NALCN | c.2221G>A p.G741R | Missense Mutation (SNP) | VAF 69/281 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.773); catalogued as rs771990457, COSV51937806, COSV51971780; called by muse, mutect2, varscan2
- NME7 | c.911C>G p.S304C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100891139; called by muse, mutect2, varscan2
- NOTCH1 | c.3643+1G>A p.X1215_splice | Splice Site (SNP) | VAF 26/86 reads (30%) | catalogued as COSV53034462, COSV99491080; called by muse, mutect2, varscan2
- NPHP4 | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1288396418, COSV65397616; called by muse, mutect2
- NSD2 | c.2881G>T p.A961S | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100373714, COSV100373763; called by muse, mutect2
- OR52E4 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV100389343; called by muse, mutect2, varscan2
- PCDHB14 | c.1550G>C p.R517T | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.12); catalogued as COSV99506208; called by muse, mutect2, varscan2
- POLI | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as rs142974796, COSV99470863; called by muse, mutect2, varscan2
- RFT1 | c.439A>G p.M147V | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV99965578; called by muse, mutect2, varscan2
- RUNX1T1 | c.669del p.T224Pfs*13 (on ENST00000265814 / NM_001198628.1; = p.T197Pfs*13 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 38/231 reads (16%) | catalogued as COSV56142566, COSV99751572; called by mutect2, pindel, varscan2
- RYR2 | c.9796A>T p.T3266S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV100772280; called by muse, mutect2, varscan2
- SCAI | c.1030A>T p.S344C (on ENST00000336505 / NM_001144877.3; = p.S367C on NM_173690.5) | Missense Mutation (SNP) | VAF 211/589 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100332984; called by muse, mutect2, varscan2
- SCUBE1 | c.1502C>G p.P501R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100683616, COSV62614379; called by muse, mutect2, varscan2
- SDC2 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as COSV100143929; called by muse, mutect2, varscan2
- SEC31A | c.2433G>T p.K811N (on ENST00000355196 / NM_001318120.1; = p.K772N on NM_016211.4) | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.656); catalogued as COSV100022239; called by muse, mutect2, varscan2
- SERPINI1 | c.968C>A p.T323K | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV99855338; called by muse, mutect2, varscan2
- SIRPD | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs561939776, COSV101064901, COSV101064972; called by muse, mutect2, varscan2
- SLC6A12 | c.1099T>G p.F367V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100675200; called by muse, mutect2, varscan2
- SPRTN | c.1132T>C p.S378P | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99150049; called by muse, mutect2, varscan2
- SPTLC1 | c.227A>T p.D76V | Missense Mutation (SNP) | VAF 57/301 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99365070; called by muse, mutect2, varscan2
- STXBP3 | c.103A>T p.M35L | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100894064; called by muse, mutect2, varscan2
- TCP11L2 | c.691A>G p.M231V | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1232346894, COSV100135514; called by muse, mutect2, varscan2
- TMEM71 | c.289G>T p.V97F | Missense Mutation (SNP) | VAF 59/316 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111461300, COSV100785680; called by muse, mutect2, varscan2
- TRPC4 | c.1122G>C p.L374F | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV100157677, COSV59022471; called by muse, mutect2, varscan2
- UNC13C | c.6634G>T p.E2212* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as rs1041881560, COSV99521990; called by muse, mutect2
- VPS33B | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 45/212 reads (21%) | catalogued as rs1057519063, CM065516, COSV60979910; called by muse, mutect2, varscan2
- WNK4 | c.3635T>A p.I1212N | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1238751452, COSV55902351; called by muse, mutect2, varscan2
- YIPF7 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs775888663, COSV100274632; called by muse, varscan2
- ZBED8 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 21/104 reads (20%) | catalogued as COSV68825188; called by muse, mutect2, varscan2
- ZIK1 | c.1237G>A p.G413R | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV100277624; called by muse, mutect2, varscan2
- ZNF12 | c.1489G>T p.E497* (on ENST00000405858 / NM_016265.4; = p.E459* on NM_006956.3) | Nonsense Mutation (SNP) | VAF 51/245 reads (21%) | catalogued as COSV100703849; called by muse, mutect2, varscan2
- ZNF236 | c.5215C>G p.R1739G | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99471070; called by muse, mutect2, varscan2
- ZNF536 | c.1878G>A p.M626I | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62817745; called by muse, mutect2, varscan2
- NR4A2 | c.1487dup p.M496Ifs*94 | Frame Shift Ins (INS) | VAF 21/95 reads (22%) | called by mutect2, pindel, varscan2
- SLITRK4 | c.762dup p.E255Rfs*15 | Frame Shift Ins (INS) | VAF 22/78 reads (28%) | called by pindel, varscan2
- USP35 | c.2491dup p.L831Pfs*16 | Frame Shift Ins (INS) | VAF 14/130 reads (11%) | called by mutect2, pindel, varscan2
- ZBTB21 | c.330dup p.I111Dfs*6 | Frame Shift Ins (INS) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- A2M | c.1194C>T p.T398= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100588917; called by muse, mutect2, varscan2
- ACTL7B | c.408C>T p.T136= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as rs1315798846, COSV101012597, COSV65927188; called by muse, mutect2, varscan2
- ATP10B | c.4360C>A p.R1454= | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as COSV100515622; called by muse, mutect2, varscan2
- CACNA1D | c.825C>A p.A275= | Silent (SNP) | VAF 40/199 reads (20%) | catalogued as COSV99859617; called by muse, mutect2, varscan2
- CCT8L2 | c.444C>T p.P148= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100743038; called by muse, mutect2, varscan2
- COL4A3 | c.4542A>T p.A1514= | Silent (SNP) | VAF 38/149 reads (26%) | catalogued as COSV101170501; called by muse, mutect2, varscan2
- CPN2 | c.891C>T p.T297= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as COSV100103246; called by muse, mutect2, varscan2
- ESM1 | c.483T>C p.I161= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as rs762980287, COSV101195701; called by muse, mutect2, varscan2
- FIGN | c.570C>T p.N190= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as rs200547675, COSV60763869; called by muse, mutect2, varscan2
- FOXC2 | c.456C>A p.S152= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as COSV57444758, COSV57445081; called by muse, mutect2, varscan2
- KCNT2 | c.3282G>A p.E1094= | Silent (SNP) | VAF 99/432 reads (23%) | catalogued as COSV99656128; called by muse, mutect2, varscan2
- KDM6B | c.4386G>A p.V1462= | Silent (SNP) | VAF 35/148 reads (24%) | catalogued as rs774880340, COSV99642127; called by muse, mutect2, varscan2
- MRC1 | c.3810G>T p.L1270= | Silent (SNP) | VAF 44/652 reads (7%) | called by muse, mutect2
- MYO5A | c.2070C>T p.I690= | Silent (SNP) | VAF 51/261 reads (20%) | catalogued as COSV100698048; called by muse, mutect2, varscan2
- NMS | c.60A>G p.L20= | Silent (SNP) | VAF 37/205 reads (18%) | catalogued as COSV100966642; called by muse, mutect2, varscan2
- PCDH10 | c.510C>T p.D170= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as rs767681896, COSV99994310; called by muse, mutect2, varscan2
- PREX2 | c.3261T>C p.F1087= | Silent (SNP) | VAF 34/210 reads (16%) | catalogued as COSV99909374; called by muse, mutect2, varscan2
- RASSF4 | c.393G>A p.E131= | Silent (SNP) | VAF 30/257 reads (12%) | catalogued as rs766929552, COSV100437200; called by muse, mutect2, varscan2
- SLC43A3 | c.1335C>T p.T445= | Silent (SNP) | VAF 48/225 reads (21%) | catalogued as rs768860779, COSV100725250; called by muse, mutect2, varscan2
- SPATA16 | c.99C>G p.T33= | Silent (SNP) | VAF 225/681 reads (33%) | catalogued as COSV100651538; called by muse, mutect2, varscan2
- TRHDE | c.2367T>C p.Y789= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs1272553891, COSV99672062; called by muse, mutect2, varscan2
- TTK | c.489A>G p.K163= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs756038032, COSV100036540; called by muse, mutect2, varscan2
- ZFAND4 | c.1635G>A p.E545= | Silent (SNP) | VAF 46/222 reads (21%) | catalogued as COSV100763079; called by muse, mutect2, varscan2
- ZNF83 | c.1107T>C p.G369= | Silent (SNP) | VAF 56/262 reads (21%) | catalogued as COSV99991523; called by muse, varscan2
- CALCA | chr11:14967785 G>T | 3'Flank (SNP) | VAF 28/113 reads (25%) | catalogued as COSV100524095; called by muse, mutect2, varscan2
- SNORD116-1 | n.40A>G | RNA (SNP) | VAF 47/233 reads (20%) | called by muse, mutect2, varscan2
- TPD52L3 | chr9:6330998 G>A | 3'Flank (SNP) | VAF 26/159 reads (16%) | catalogued as rs192550349, COSV58828515; called by muse, mutect2, varscan2
